Somatic mutation profile of tumor specimen ALCH-ABV0-TTP1-A (aliquot ALCH-ABV0-TTP1-A-1-0-D-A489-36) from ALCHEMIST case ALCH-ABV0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.8 years (26,960 days).
Specimen ALCH-ABV0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ea49faf-1e98-4a8d-ba88-a4d68f260794.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABV0-NB1-A (Blood Derived Normal), aliquot ALCH-ABV0-NB1-A-1-0-D-A489-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09c063f2-a571-48a0-8fe4-f82a75665373

The open-access MAF lists 169 somatic variants for this specimen: 112 protein-altering or splice-affecting, 38 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 38, Intron 15, Nonsense Mutation 9, Splice Region 2, Frame Shift Ins 2, Frame Shift Del 2, 3'UTR 2, 5'Flank 1, Splice Site 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2237_2251del p.E746_T751delinsA | In Frame Del (DEL) | VAF 210/1035 reads (20%) | hotspot (GDC flag); catalogued as rs121913425, COSV51766481, COSV51769364, COSV51779850, COSV51794924, COSV51856180, COSV51859776; ClinVar: drug response; called by mutect2, pindel, varscan2
- AP002512.3 | c.636C>A p.H212Q | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.872); catalogued as COSV54408056; called by muse, mutect2
- BSG | c.1060G>T p.V354F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV61078416; called by muse, varscan2
- CCDC27 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV53899509; called by muse, varscan2
- CMBL | c.558C>T p.D186= | Splice Region (SNP) | VAF 50/355 reads (14%) | catalogued as rs201168993, COSV56983801; called by muse, mutect2, varscan2
- FAM135B | c.203A>G p.H68R | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs752863709; called by muse, mutect2, varscan2
- FAR1 | c.205A>G p.R69G | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs770071264; called by muse, varscan2
- GABRA1 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 50/371 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99195735; called by muse, varscan2
- GLO1 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100974072; called by muse, mutect2, varscan2
- GRID1 | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 46/336 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.333); catalogued as rs752023884, COSV60022117; called by muse, mutect2, varscan2
- GRIN2A | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV58027192; called by muse, mutect2, varscan2
- GRIN3A | c.2665G>T p.E889* | Nonsense Mutation (SNP) | VAF 85/669 reads (13%) | catalogued as COSV100701812; called by muse, mutect2, varscan2
- KAT6B | c.5411G>T p.G1804V | Missense Mutation (SNP) | VAF 120/810 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54754616; called by muse, mutect2, varscan2
- KRT23 | c.874C>A p.R292S | Missense Mutation (SNP) | VAF 88/650 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs371648763; called by muse, mutect2, varscan2
- MED29 | c.385G>C p.E129Q (on ENST00000615911; = p.E108Q on NM_017592.4) | Missense Mutation (SNP) | VAF 14/489 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV55396001; called by muse, mutect2
- MEOX2 | c.758C>A p.A253E | Missense Mutation (SNP) | VAF 77/726 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as rs766320553, COSV100012023; called by muse, varscan2
- MTF1 | c.1525G>T p.A509S | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100888654; called by muse, mutect2, varscan2
- MUC16 | c.30221C>A p.P10074Q | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.918); catalogued as COSV67453330; called by muse, mutect2, varscan2
- MYO15A | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV52761657; called by muse, mutect2, varscan2
- NLRP14 | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 68/577 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100205280; called by muse, mutect2, varscan2
- OBSCN | c.13180G>A p.G4394S | Missense Mutation (SNP) | VAF 19/497 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209356254, COSV52770996; called by muse, mutect2
- OR4K1 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as COSV99578649; called by muse, mutect2, varscan2
- PABPN1 | c.662C>A p.S221* | Nonsense Mutation (SNP) | VAF 36/870 reads (4%) | catalogued as COSV53729040; called by muse, mutect2
- PABPN1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 35/842 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1165283571; called by muse, mutect2
- POTEE | c.2569G>T p.D857Y | Missense Mutation (SNP) | VAF 159/798 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs750345024; called by muse, varscan2
- PROX2 | c.260C>A p.A87E | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs777017206, COSV71520241; called by muse, mutect2, varscan2
- PTCHD4 | c.559del p.Q187Kfs*4 | Frame Shift Del (DEL) | VAF 61/448 reads (14%) | catalogued as COSV59779955; called by mutect2, pindel, varscan2
- RYR3 | c.5728C>A p.P1910T | Missense Mutation (SNP) | VAF 34/454 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.603); catalogued as COSV99081143; called by muse, mutect2
- SCN3A | c.3721G>A p.E1241K | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV51818330; called by muse, mutect2, varscan2
- SERPINI1 | c.593A>G p.N198S | Missense Mutation (SNP) | VAF 67/343 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs1296801193; called by muse, mutect2, varscan2
- SLC35F4 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1338858150; called by muse, mutect2, varscan2
- SLC38A7 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 106/439 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.416); catalogued as rs370282423; called by muse, mutect2, varscan2
- SON | c.2863C>T p.P955S | Missense Mutation (SNP) | VAF 71/467 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs181683333, COSV51654844; called by muse, mutect2, varscan2
- TAFA5 | c.179C>T p.T60M (on ENST00000402357 / NM_001082967.3; = p.T53M on NM_015381.7) | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); catalogued as rs373045207; called by muse, mutect2, varscan2
- TENM4 | c.3050C>A p.A1017D | Missense Mutation (SNP) | VAF 59/339 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.086); catalogued as COSV53624692; called by muse, mutect2, varscan2
- TKTL2 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as COSV54920008; called by muse, mutect2, varscan2
- TTN | c.318C>A p.F106L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | PolyPhen probably damaging (0.991); catalogued as COSV59863189; called by muse, mutect2, varscan2
- URB2 | c.3899C>T p.A1300V | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1306291673; called by muse, mutect2, varscan2
- YME1L1 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV58761545; called by muse, mutect2, varscan2
- ZNF275 | c.794T>A p.F265Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.214); catalogued as rs782065446; called by muse, mutect2, varscan2
- ADAMTSL4 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 13/439 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ADCY8 | c.3398C>T p.P1133L | Missense Mutation (SNP) | VAF 65/786 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AGBL1 | c.1328A>C p.Q443P | Missense Mutation (SNP) | VAF 30/375 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- ALDOA | c.767G>C p.C256S (on ENST00000642816 / NM_001243177.4; = p.C202S on NM_184041.5) | Missense Mutation (SNP) | VAF 179/1166 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- ARHGAP30 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 106/454 reads (23%) | called by muse, mutect2, varscan2
- ATXN2 | c.3756G>T p.Q1252H (on ENST00000550104; = p.Q1092H on NM_002973.4) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- B3GALT4 | c.367T>G p.S123A | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.018); called by muse, mutect2
- BICD2 | c.607G>C p.V203L | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2
- BMP15 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CALCOCO2 | c.428A>G p.E143G | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CAVIN4 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 23/630 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2
- CCT5 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 132/461 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.4340T>C p.V1447A (on ENST00000297405 / NM_001363185.1; = p.V1343A on NM_052900.3) | Missense Mutation (SNP) | VAF 22/516 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.901); called by muse, mutect2
- DCT | c.1521G>C p.E507D | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGKB | c.1710del p.D570Efs*33 | Frame Shift Del (DEL) | VAF 34/296 reads (11%) | called by mutect2, varscan2
- DNAH9 | c.93C>A p.Y31* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- DOCK2 | c.1738dup p.A580Gfs*88 | Frame Shift Ins (INS) | VAF 13/120 reads (11%) | called by mutect2, pindel, varscan2
- DRP2 | c.742A>T p.S248C | Missense Mutation (SNP) | VAF 72/558 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- EBF1 | c.954C>A p.H318Q | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- EFCC1 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 32/309 reads (10%) | called by muse, mutect2, varscan2
- EPHA6 | c.2597T>A p.V866D (on ENST00000389672 / NM_001080448.3; = p.V258D on NM_173655.4) | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM171A1 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FASLG | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 28/928 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2
- FHAD1 | c.2241A>C p.R747S | Missense Mutation (SNP) | VAF 84/415 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- FSCB | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.02); called by muse, varscan2
- GAB2 | c.854C>G p.S285C (on ENST00000361507 / NM_080491.3; = p.S247C on NM_012296.3) | Missense Mutation (SNP) | VAF 88/930 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); called by muse, mutect2
- HAS2 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 41/390 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNF4G | c.313A>G p.N105D (on ENST00000354370 / NM_001330561.2; = p.N152D on NM_004133.5) | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- HYDIN | c.6356G>T p.G2119V | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HYDIN | c.6355G>T p.G2119* | Nonsense Mutation (SNP) | VAF 37/262 reads (14%) | called by muse, mutect2, varscan2
- ITPRID1 | c.1731G>T p.Q577H | Missense Mutation (SNP) | VAF 74/291 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- KCNQ3 | c.1894A>T p.M632L | Missense Mutation (SNP) | VAF 62/744 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- KIF17 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 34/547 reads (6%) | called by muse, mutect2
- KIF26B | c.2372C>T p.T791I | Missense Mutation (SNP) | VAF 29/282 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- LILRA6 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 156/606 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRBA | c.5392G>C p.E1798Q | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.617); called by muse, mutect2
- LUZP4 | c.251A>T p.E84V | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- MAGEB1 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 75/413 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAGEL2 | c.3626C>A p.P1209Q | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP10 | c.2274A>C p.E758D | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, varscan2
- MBTPS2 | c.1338G>T p.K446N | Missense Mutation (SNP) | VAF 61/549 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MICAL3 | c.2050A>G p.T684A | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- MITF | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, varscan2
- MKKS | c.497delinsCC p.L166Pfs*26 | Frame Shift Ins (INS) | VAF 40/410 reads (10%) | called by mutect2*, pindel
- MUC16 | c.25765C>A p.P8589T | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MYH4 | c.3017C>A p.A1006D | Missense Mutation (SNP) | VAF 114/744 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NAV3 | c.1039A>C p.M347L | Missense Mutation (SNP) | VAF 106/718 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- NEB | c.5526G>T p.K1842N | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NIN | c.5797G>A p.E1933K (on ENST00000382041 / NM_182946.1; = p.E1220K on NM_016350.4) | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OTOF | c.2713A>T p.T905S (on ENST00000272371 / NM_194248.3; = p.T158S on NM_004802.4) | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- PAPLN | c.331A>T p.S111C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, varscan2
- PCDH15 | c.75G>T p.L25F | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, varscan2
- PCDHGA4 | c.1829C>A p.P610H | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF8 | c.2370C>A p.S790R (on ENST00000357988 / NM_001184896.1; = p.S754R on NM_015107.3) | Missense Mutation (SNP) | VAF 63/368 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PKD1L1 | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 84/309 reads (27%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- POM121L12 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 116/385 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM6 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 67/305 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PSG9 | c.946T>C p.Y316H | Missense Mutation (SNP) | VAF 106/408 reads (26%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- RACGAP1 | c.388A>G p.R130G | Missense Mutation (SNP) | VAF 13/262 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.079); called by muse, mutect2
- SCN4A | c.2022G>A p.L674= | Splice Region (SNP) | VAF 9/50 reads (18%) | called by muse, varscan2
- SGMS1 | c.128A>G p.D43G | Missense Mutation (SNP) | VAF 76/593 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SRGN | c.77A>T p.Q26L | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TBC1D1 | c.883-2A>T p.X295_splice | Splice Site (SNP) | VAF 38/198 reads (19%) | called by muse, mutect2, varscan2
- TBCK | c.242T>A p.L81* | Nonsense Mutation (SNP) | VAF 56/426 reads (13%) | called by muse, mutect2, varscan2
- TENM2 | c.1138G>T p.A380S (on ENST00000518659 / NM_001122679.2; = p.A189S on NM_001080428.3) | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- TSHZ3 | c.1128G>T p.W376C | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- TSHZ3 | c.1127G>A p.W376* | Nonsense Mutation (SNP) | VAF 33/118 reads (28%) | called by muse, mutect2, varscan2
- ZDHHC3 | c.232A>T p.I78F | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2
- ZNF32 | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF418 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 79/288 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, varscan2
- ZNF648 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 78/585 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ZNF652 | c.434C>G p.P145R | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- ADRB3 | c.282G>A p.A94= | Silent (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- ASTE1 | c.360G>T p.R120= | Silent (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2
- CRNKL1 | c.2514T>C p.H838= | Silent (SNP) | VAF 49/348 reads (14%) | called by mutect2, varscan2
- DACH1 | c.693C>A p.T231= | Silent (SNP) | VAF 37/364 reads (10%) | called by muse, mutect2
- DNAH1 | c.5016A>T p.P1672= | Silent (SNP) | VAF 58/314 reads (18%) | called by muse, mutect2, varscan2
- DNHD1 | c.13047G>C p.G4349= | Silent (SNP) | VAF 27/170 reads (16%) | called by muse, mutect2, varscan2
- FANCD2 | c.615G>A p.E205= | Silent (SNP) | VAF 17/456 reads (4%) | called by muse, mutect2
- FOXR2 | c.699G>C p.P233= | Silent (SNP) | VAF 60/493 reads (12%) | called by mutect2, varscan2
- IL4R | c.1401G>T p.L467= | Silent (SNP) | VAF 21/206 reads (10%) | called by muse, mutect2, varscan2
- IRS1 | c.2211A>G p.P737= | Silent (SNP) | VAF 64/891 reads (7%) | catalogued as rs1472621296, CM004558; called by muse, mutect2
- ITK | c.24A>G p.E8= | Silent (SNP) | VAF 56/549 reads (10%) | called by muse, mutect2, varscan2
- LARGE2 | c.420C>T p.I140= | Silent (SNP) | VAF 86/422 reads (20%) | catalogued as rs781607068; called by muse, mutect2, varscan2
- LCT | c.3600G>A p.T1200= | Silent (SNP) | VAF 39/117 reads (33%) | catalogued as rs775945344; called by muse, mutect2, varscan2
- MAGEB3 | c.501T>C p.D167= | Silent (SNP) | VAF 55/310 reads (18%) | called by muse, mutect2, varscan2
- MED12 | c.2953T>C p.L985= | Silent (SNP) | VAF 65/594 reads (11%) | called by muse, mutect2, varscan2
- MPP1 | c.813C>T p.Y271= | Silent (SNP) | VAF 18/588 reads (3%) | catalogued as rs148577076; called by muse, mutect2
- MTO1 | c.720A>C p.P240= | Silent (SNP) | VAF 41/427 reads (10%) | called by muse, mutect2
- MYH2 | c.567C>A p.T189= | Silent (SNP) | VAF 26/795 reads (3%) | called by muse, mutect2
- MYO3B | c.297G>A p.G99= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as rs745764853; called by muse, mutect2, varscan2
- N4BP1 | c.435G>A p.E145= | Silent (SNP) | VAF 38/246 reads (15%) | catalogued as COSV99284730; called by muse, mutect2, varscan2
- NFE2 | c.936C>T p.R312= | Silent (SNP) | VAF 14/314 reads (4%) | called by muse, mutect2
- NPIPB2 | c.105C>T p.D35= | Silent (SNP) | VAF 86/688 reads (13%) | called by muse, mutect2, varscan2
- OTUD6A | c.96G>T p.S32= | Silent (SNP) | VAF 54/360 reads (15%) | called by muse, mutect2, varscan2
- PARP1 | c.354C>G p.A118= | Silent (SNP) | VAF 38/968 reads (4%) | called by muse, mutect2
- PCDHA2 | c.1986G>T p.T662= | Silent (SNP) | VAF 73/345 reads (21%) | catalogued as COSV65371708; called by muse, mutect2, varscan2
- PCDHB11 | c.1581C>T p.F527= | Silent (SNP) | VAF 46/1041 reads (4%) | catalogued as rs868988714, COSV61309851; called by muse, mutect2
- PIAS1 | c.651C>T p.P217= | Silent (SNP) | VAF 36/421 reads (9%) | called by muse, mutect2
- POTEG | c.1020G>T p.T340= | Silent (SNP) | VAF 82/528 reads (16%) | catalogued as rs746155420; called by mutect2, varscan2
- PTPRC | c.1422A>T p.A474= | Silent (SNP) | VAF 51/483 reads (11%) | called by muse, varscan2
- RAI2 | c.387C>T p.H129= | Silent (SNP) | VAF 15/159 reads (9%) | catalogued as rs774957359; called by muse, mutect2
- RAVER2 | c.897C>T p.G299= | Silent (SNP) | VAF 50/327 reads (15%) | called by muse, mutect2, varscan2
- TDRD15 | c.1695T>C p.F565= | Silent (SNP) | VAF 48/186 reads (26%) | called by muse, varscan2
- TENM2 | c.1137C>T p.S379= (on ENST00000518659 / NM_001122679.2; = p.S188= on NM_001080428.3) | Silent (SNP) | VAF 66/339 reads (19%) | catalogued as rs372788219; called by muse, mutect2, varscan2
- TENM3 | c.657G>T p.P219= | Silent (SNP) | VAF 96/698 reads (14%) | called by muse, mutect2, varscan2
- TTBK1 | c.1587G>T p.S529= | Silent (SNP) | VAF 67/362 reads (19%) | called by muse, mutect2, varscan2
- UBA7 | c.2760A>T p.P920= | Silent (SNP) | VAF 27/401 reads (7%) | called by muse, mutect2
- USP27X | c.666G>A p.T222= | Silent (SNP) | VAF 28/225 reads (12%) | catalogued as rs1238802146; called by muse, mutect2, varscan2
- VEGFD | c.120T>C p.S40= | Silent (SNP) | VAF 48/424 reads (11%) | called by muse, mutect2, varscan2
- ABCG5 | c.266-20C>T | Intron (SNP) | VAF 110/454 reads (24%) | called by muse, mutect2, varscan2
- ACTG1 | c.-409C>T | 5'UTR (SNP) | VAF 23/112 reads (21%) | catalogued as rs782806224; called by muse, mutect2, varscan2
- APOA2 | c.53-25del | Intron (DEL) | VAF 47/266 reads (18%) | called by muse*, mutect2
- ASH1L | chr1:155563522 C>A | 5'Flank (SNP) | VAF 54/1356 reads (4%) | called by muse, mutect2
- C2 | c.443-1137G>T | Intron (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- CSF2RA | c.1125+171G>T | Intron (SNP) | VAF 38/432 reads (9%) | called by muse, mutect2
- DCX | c.-22-603G>T | Intron (SNP) | VAF 40/270 reads (15%) | catalogued as rs568674887; called by muse, mutect2, varscan2
- FLNC | c.2007+23C>A | Intron (SNP) | VAF 14/468 reads (3%) | called by muse, mutect2
- GABRA1 | c.1059+34T>A | Intron (SNP) | VAF 45/316 reads (14%) | called by muse, mutect2, varscan2
- GNPTG | c.53-17G>A | Intron (SNP) | VAF 25/191 reads (13%) | called by muse, mutect2, varscan2
- H2BC18 | c.378-9734G>T | Intron (SNP) | VAF 41/382 reads (11%) | catalogued as rs1182440723; called by muse, mutect2, varscan2
- LIMK2 | c.117-9616A>G | Intron (SNP) | VAF 152/957 reads (16%) | catalogued as rs766149569; called by muse, mutect2, varscan2
- LINC00452 | n.612-3559C>A | Intron (SNP) | VAF 30/182 reads (16%) | called by muse, varscan2
- MAGEC3 | c.1124-17C>T | Intron (SNP) | VAF 156/879 reads (18%) | called by muse, mutect2, varscan2
- RPS2 | c.376-108A>G | Intron (SNP) | VAF 15/269 reads (6%) | catalogued as rs1567317369; called by muse, mutect2
- TNPO2 | c.-13-358C>T | Intron (SNP) | VAF 12/57 reads (21%) | catalogued as COSV63509647; called by muse, mutect2, varscan2
- TRADD | c.*29C>T | 3'UTR (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- TSC1 | c.*23A>G | 3'UTR (SNP) | VAF 49/318 reads (15%) | called by muse, mutect2, varscan2
- USE1 | c.395-32C>A | Intron (SNP) | VAF 42/162 reads (26%) | called by muse, mutect2, varscan2
